CPTAC case C3L-01464 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/44d4ed0f-204b-40ce-9345-72ac30f6a3a1

Demographics
Sex at birth: male; Race: white; Year of birth: 1938; Vital status: Alive.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 78.7 years (28,740 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T3a; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Tumor grade: G4; Residual disease: RX; Days to last known disease status: 1,520 days (4.2 years); Days to last follow up: 1,520 days (4.2 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 10.5 cm (a second GDC size field records 3.2 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Indeterminate; Sarcomatoid present: No.

Follow-up (5 entries)
- Days to follow up: 375 days (1.0 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 711 days (1.9 years); Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,142 days (3.1 years); Disease response: Complete Response; Progression or recurrence: Yes; Days to recurrence: 1,118 days (3.1 years); Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,142 days (3.1 years); Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,520 days (4.2 years); Karnofsky performance status: 100; ECOG performance status: 0.

Other clinical attributes
- Weight: 76.2 kg; Height: 177.8 cm; BMI: 24.1.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-01464-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 200 mg; Time between excision and freezing: 23 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-01464-21: Section location: Tumor occupies the mid to lower poles; Percent tumor nuclei: 90; Percent necrosis: 2.
- Sample C3L-01464-02: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 90 mg; Time between excision and freezing: 25 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-01464-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
- Sample C3L-01464-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
